TCGA case TCGA-CH-5789 — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Acinar Cell Neoplasms; Primary site: Prostate gland; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/be5411dc-3caa-4b25-9b94-ce463e8e52b4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Acinar cell carcinoma: ICD-O-3 morphology code: 8550/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 61.6 years (22,494 days); Year of diagnosis: 2006; Method of diagnosis: Core Biopsy; AJCC clinical M: M0; AJCC pathologic T: T3a; AJCC pathologic N: N0; Primary gleason grade: Pattern 3; Secondary gleason grade: Pattern 4; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Gleason score: 7.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 4; Zone of origin prostate: Peripheral zone.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Day 61 (initial diagnosis): Days to imaging: 61 days; Imaging type: CT Scan; Imaging anatomic site: Abdomen / Pelvis; Imaging findings: No Evidence of Extraprostatic Extension.
- Days to follow up: 304 days; Disease response: Tumor Free.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 0.02 ng/mL (day 229).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CH-5789-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1; Intermediate dimension: 0.4; Shortest dimension: 0.4.
  Slide TCGA-CH-5789-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-CH-5789-01A-01-TS1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 70; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-CH-5789-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Method initial path diagnosis: Core needle biopsy; Ct scan ab pelvis indicator: Yes; Biochemical recurrence indicator: No.
- Stage record, Psa: PSA most recent results: 0.02.
- Stage record, Gleason grading: Gleason pattern primary: 3; Gleason pattern secondary: 4.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 304 days; disease-specific survival: no event (censored), 304 days; disease-free interval: no event (censored), 304 days; progression-free interval: no event (censored), 304 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CH-5789-01A-11D-1574-01): tumor purity 1, ploidy 2, whole-genome doublings 0.
